Somatic mutation profile of tumor specimen TCGA-32-2632-01A (aliquot TCGA-32-2632-01A-01W-0922-08) from TCGA case TCGA-32-2632, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.2 years (29,281 days).
Specimen TCGA-32-2632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6882e93d-e5fc-4c7d-839c-69c06d3e2cc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2632-10A (Blood Derived Normal), aliquot TCGA-32-2632-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bdd25b1-f5b8-4b6b-8acd-d44154ae44bf

The open-access MAF lists 90 somatic variants for this specimen: 70 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 17, Nonsense Mutation 6, Frame Shift Ins 3, Intron 1, Splice Site 1, 3'UTR 1, Splice Region 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 2503/2638 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, varscan2
- PTEN | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 17/228 reads (7%) | hotspot (GDC flag); catalogued as rs786204929, CM122894, COSV64288557, COSV64309376; called by muse, mutect2
- RB1 | c.1024del p.T342Lfs*7 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | catalogued as rs587778844, CM144108, COSV99927802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA9 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as COSV60629747; called by muse, mutect2
- ABCB5 | c.2377G>A p.G793S (on ENST00000404938 / NM_001163941.2; = p.G348S on NM_178559.6) | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV51718271; called by muse, mutect2, varscan2
- ABCD3 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64644218; called by muse, mutect2
- AC004593.2 | c.1082A>C p.H361P | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56099721; called by muse, varscan2
- ADAM32 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as rs757189886, COSV65948045; called by muse, mutect2, varscan2
- AQP9 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 60/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99582960; called by muse, mutect2, varscan2
- ASPM | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54136561; called by muse, mutect2, varscan2
- CABYR | c.216A>T p.E72D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV59112319; called by muse, mutect2, varscan2
- CALN1 | c.503C>T p.S168L (on ENST00000329008 / NM_001017440.3; = p.S210L on NM_031468.4) | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs143545775; called by muse, mutect2, varscan2
- CCL14 | c.136C>T p.R46C (on ENST00000618404 / NM_032963.4; = p.R62C on NM_032962.4) | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs372808751; called by muse, mutect2, varscan2
- CELSR3 | c.691dup p.R231Pfs*73 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | catalogued as rs758559794; called by mutect2, pindel, varscan2
- CENPE | c.7030A>G p.K2344E | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.681); catalogued as COSV54388031; called by muse, mutect2, varscan2
- CFAP20DC | c.748C>T p.R250W (on ENST00000482387 / NM_001351530.2; = p.R125W on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs756677660, COSV55925989; called by muse, mutect2, varscan2
- CIP2A | c.1827+1G>A p.X609_splice | Splice Site (SNP) | VAF 28/134 reads (21%) | catalogued as COSV55420745; called by muse, mutect2, varscan2
- CLYBL | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV59227179; called by muse, mutect2, varscan2
- CNTNAP5 | c.2540A>G p.E847G | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1294640842, COSV70506926; called by muse, varscan2
- COL6A5 | c.6709A>T p.S2237C (on ENST00000312481; = p.S2233C on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV55213228; called by muse, mutect2, varscan2
- CYP4F22 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs146265982, COSV54106998; called by muse, mutect2, varscan2
- DCSTAMP | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV52579577; called by muse, mutect2, varscan2
- DDX4 | c.1020G>A p.A340= | Splice Region (SNP) | VAF 119/277 reads (43%) | catalogued as COSV61756758; called by muse, mutect2, varscan2
- DOCK5 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52396789; called by muse, mutect2, varscan2
- DOCK5 | c.1939T>A p.S647T | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52409127; called by muse, mutect2, varscan2
- EFCAB6 | c.3917C>T p.P1306L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1292409726, COSV53070442; called by muse, mutect2, varscan2
- F5 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV63127222; called by muse, mutect2
- FAM81B | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.275); catalogued as COSV51986151; called by muse, mutect2, varscan2
- FLG | c.6470C>T p.S2157L | Missense Mutation (SNP) | VAF 252/704 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs761306814, COSV64237796; called by muse, mutect2, varscan2
- GABRA1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 96/212 reads (45%) | catalogued as COSV50115651; called by muse, mutect2, varscan2
- GCC1 | c.2227C>G p.L743V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58463556; called by muse, mutect2, varscan2
- GRIN2A | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 167/536 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1489261681, COSV58032859, COSV58037182; ClinVar: not provided; called by muse, mutect2, varscan2
- HDAC2 | c.1171C>G p.H391D | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64039265; called by muse, mutect2, varscan2
- HYDIN | c.13792G>A p.V4598M | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV66641615; called by muse, mutect2, varscan2
- IGKV3D-11 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1311393754; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1998C>A p.H666Q | Missense Mutation (SNP) | VAF 93/134 reads (69%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV61175953; called by muse, mutect2, varscan2
- ING2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56564128; called by muse, mutect2, varscan2
- LILRB1 | c.1825C>A p.Q609K (on ENST00000427581; = p.Q558K on NM_006669.6) | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV61121060; called by muse, mutect2, varscan2
- LTBP2 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs551341275, COSV56205068; called by muse, mutect2, varscan2
- LTN1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375416726; called by muse, mutect2, varscan2
- MCHR2 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56007388, COSV99912382; called by muse, mutect2, varscan2
- MGAM | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 323/1324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1554466069, COSV101527763, COSV72075408; called by muse, mutect2, varscan2
- MMRN1 | c.2018T>C p.V673A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777048531; called by muse, mutect2, varscan2
- MYH7 | c.5729C>T p.A1910V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1454105335, COSV62522799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3B | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 256/498 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753265274, COSV100508992; called by muse, mutect2
- NDN | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV59361139; called by muse, mutect2, varscan2
- NIPAL4 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV61729938, COSV61730965; called by muse, mutect2, varscan2
- NOTCH2 | c.5123C>G p.S1708C | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV56687314, COSV56702208; called by muse, mutect2, varscan2
- NRXN3 | c.2026G>C p.G676R (on ENST00000335750 / NM_001330195.2; = p.G303R on NM_004796.6) | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV59795755; called by muse, mutect2, varscan2
- NUP214 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 80/180 reads (44%) | catalogued as rs1427146168, COSV63912364; called by muse, varscan2
- OR6M1 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368975645; called by muse, mutect2, varscan2
- PIK3CG | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1462539802, COSV63248803; called by muse, mutect2
- PIK3CG | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63252250; called by muse, mutect2, varscan2
- QPCT | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV58120953; called by muse, mutect2, varscan2
- RAPGEF6 | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV57253891; called by muse, mutect2
- RDH8 | c.653C>T p.A218V (on ENST00000651512; = p.A198V on NM_015725.4) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.355); catalogued as rs754093769, COSV50675550; called by muse, mutect2, varscan2
- RELT | c.303G>C p.W101C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV50362432; called by muse, mutect2, varscan2
- SEMG1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs141417035, COSV54872621, COSV54873769; called by muse, mutect2, varscan2
- SLC5A7 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 236/511 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50889216; called by muse, mutect2, varscan2
- SPTA1 | c.4201C>G p.Q1401E | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV100935056, COSV63757909; called by muse, mutect2, varscan2
- TDRD9 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 96/282 reads (34%) | catalogued as rs143367834; called by muse, mutect2, varscan2
- TRHDE | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs770977159, COSV53861169, COSV99670324; called by muse, mutect2, varscan2
- TTC17 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV50016250; called by muse, mutect2, varscan2
- TTN | c.58010A>G p.E19337G (on ENST00000591111; = p.E11913G on NM_003319.4) | Missense Mutation (SNP) | VAF 51/95 reads (54%) | PolyPhen possibly damaging (0.737); catalogued as COSV60279141; called by muse, mutect2, varscan2
- ZNF599 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61397229; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626dup p.N209Kfs*2 | Frame Shift Ins (INS) | VAF 82/124 reads (66%) | called by mutect2, varscan2
- CA3 | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | called by muse, varscan2
- CCDC107 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GLMN | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- TBC1D23 | c.469dup p.I157Nfs*23 | Frame Shift Ins (INS) | VAF 33/140 reads (24%) | called by mutect2, pindel, varscan2
- ATP11A | c.1329C>T p.N443= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs760113692, COSV52120995; called by muse, mutect2, varscan2
- CCDC8 | c.1410G>A p.R470= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100281926, COSV56774485; called by muse, mutect2, varscan2
- DMD | c.2964T>C p.S988= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV63783421; called by muse, mutect2
- DOCK5 | c.5175C>T p.S1725= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs768511425, COSV52409137; called by muse, mutect2, varscan2
- GPR78 | c.810C>T p.T270= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs760367219, COSV66763810; called by muse, mutect2
- JPH1 | c.768G>A p.T256= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV60614037; called by muse, mutect2, varscan2
- KRT38 | c.144C>T p.N48= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs369697357; called by muse, mutect2, varscan2
- LSMEM2 | c.306C>T p.L102= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs116862338; called by muse, mutect2, varscan2
- MAP7 | c.1587G>A p.E529= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV63422339; called by muse, mutect2, varscan2
- MEP1B | c.495G>A p.S165= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs759506843, COSV52498985; called by muse, mutect2, varscan2
- OR4X1 | c.327G>A p.E109= | Silent (SNP) | VAF 95/267 reads (36%) | catalogued as COSV60723685; called by muse, mutect2, varscan2
- PHF20 | c.2559G>A p.Q853= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV64977341; called by muse, mutect2, varscan2
- PTK2B | c.2475G>A p.E825= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs766407905, COSV57752833; called by muse, mutect2, varscan2
- SCN7A | c.3267C>T p.D1089= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV69274085; called by muse, mutect2, varscan2
- SLC6A18 | c.1515G>A p.A505= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs202091732, COSV57251096; called by muse, mutect2, varscan2
- TNFRSF11A | c.219G>A p.P73= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as rs780909910, COSV54024687; called by muse, mutect2, varscan2
- TRMT44 | c.1935A>G p.L645= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs533799281, COSV67664746; called by muse, mutect2, varscan2
- LEKR1 | c.*1389C>T | 3'UTR (SNP) | VAF 79/225 reads (35%) | catalogued as COSV62960249; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397702 G>T | 3'Flank (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.34354+583A>T | Intron (SNP) | VAF 32/139 reads (23%) | catalogued as COSV60279167; called by muse, mutect2, varscan2
